Somatic mutation profile of tumor specimen TCGA-KL-8329-01A (aliquot TCGA-KL-8329-01A-11D-2310-10) from TCGA case TCGA-KL-8329, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 57.4 years (20,972 days).
Specimen TCGA-KL-8329-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c687545f-393c-4f57-9b19-82b7ad58c2b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KL-8329-11A (Solid Tissue Normal), aliquot TCGA-KL-8329-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4f219e4-5484-4088-b1b1-92d860bc1a41

The open-access MAF lists 27 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, Intron 2, Nonsense Mutation 2, RNA 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 7/95 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2
- B4GALNT1 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as rs762195452, COSV100246953; called by muse, mutect2, varscan2
- CASKIN2 | c.701C>T p.T234I | Missense Mutation (SNP) | VAF 42/57 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1381190125, COSV100395282; called by muse, mutect2, varscan2
- CCDC180 | c.3952C>T p.L1318F | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.019); catalogued as COSV100826569; called by muse, mutect2, varscan2
- CDKN1A | c.293C>A p.S98* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV55188588, COSV55190422; called by muse, mutect2, varscan2
- KAT14 | c.1733T>C p.V578A | Missense Mutation (SNP) | VAF 15/289 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV100890035; called by muse, mutect2
- MCM3AP | c.105A>T p.Q35H | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV99386485; called by muse, mutect2, varscan2
- MTMR10 | c.1828T>A p.L610I | Missense Mutation (SNP) | VAF 139/338 reads (41%) | SIFT tolerated (1); PolyPhen possibly damaging (0.721); catalogued as COSV100075910; called by muse, mutect2, varscan2
- OR1Q1 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 75/173 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs1397350258, COSV52918020, COSV52919601; called by muse, mutect2, varscan2
- OR5H15 | c.643C>G p.L215V | Missense Mutation (SNP) | VAF 82/436 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.248); catalogued as COSV100736614, COSV62947866; called by muse, mutect2, varscan2
- OTUD7A | c.1343C>T p.T448M (on ENST00000307050 / NM_001382637.1; = p.T441M on NM_130901.3) | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs779792575, COSV61037466; called by muse, mutect2, varscan2
- PAXBP1 | c.827C>A p.S276Y | Missense Mutation (SNP) | VAF 80/259 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV99269033; called by muse, mutect2, varscan2
- PCDHA8 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.786); catalogued as COSV65334857; called by muse, mutect2, varscan2
- PLAA | c.2052G>A p.M684I | Missense Mutation (SNP) | VAF 11/281 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs999088245, COSV101263485; called by muse, mutect2
- PTEN | c.794T>A p.L265Q | Missense Mutation (SNP) | VAF 39/58 reads (67%) | SIFT tolerated (0.15); PolyPhen benign (0.399); catalogued as COSV100909467; called by muse, mutect2, varscan2
- SCAMP1 | c.658G>T p.V220L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as rs1237841667, COSV100210324; called by muse, mutect2, varscan2
- TP53 | c.687T>A p.C229* | Nonsense Mutation (SNP) | VAF 14/87 reads (16%) | catalogued as CD076915, COSV52903842, COSV53757768; called by muse, mutect2, varscan2
- IQGAP1 | c.4105_4117del p.F1369Efs*14 | Frame Shift Del (DEL) | VAF 56/154 reads (36%) | called by mutect2, pindel, varscan2
- ZNF225 | c.378_381dup p.D128Tfs*3 | Frame Shift Ins (INS) | VAF 89/231 reads (39%) | called by mutect2, varscan2
- AKAP12 | c.1956A>G p.E652= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV99482446; called by muse, mutect2, varscan2
- KRIT1 | c.1419A>G p.Q473= | Silent (SNP) | VAF 21/186 reads (11%) | catalogued as rs748732288, CM150783, COSV100388605; called by muse, mutect2, varscan2
- POLA2 | c.840G>A p.S280= | Silent (SNP) | VAF 48/158 reads (30%) | catalogued as rs372693281; called by muse, mutect2, varscan2
- SPATA31E1 | c.3336G>T p.L1112= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as COSV100349945; called by muse, mutect2, varscan2
- WASHC4 | c.141C>T p.D47= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs368178226; ClinVar: likely benign; called by muse, mutect2, varscan2
- AC024598.1 | c.1130-1009A>T | Intron (SNP) | VAF 50/70 reads (71%) | catalogued as COSV100760274; called by muse, mutect2, varscan2
- DCHS2 | n.4787G>A | RNA (SNP) | VAF 85/277 reads (31%) | catalogued as rs142512414; called by muse, mutect2, varscan2
- KIF1B | c.2115+7343G>T | Intron (SNP) | VAF 45/105 reads (43%) | catalogued as COSV55813325, COSV99822492; called by muse, mutect2, varscan2
